CPTAC case C3N-01815 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b43d423-a9ae-46b4-8888-40e30c8bc17b

Demographics
Sex at birth: female; Race: asian; Year of birth: 1946; Vital status: Dead; Days to death: 121 days; Year of death: 2017; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 71.1 years (25,973 days); Year of diagnosis: 2017; Days to last known disease status: 121 days; Days to last follow up: 96 days.
   Pathology details: Greatest tumor dimension: 5 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 96.

Other clinical attributes
- Weight: 58 kg; Height: 158 cm; BMI: 23.23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (10 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01815-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 300 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01815-21: Section location: Left Hemisphere; Percent tumor nuclei: 75; Percent necrosis: 15.
- Samples C3N-01815-02, C3N-01815-03 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 100 mg.
- Samples C3N-01815-31, C3N-01815-32, C3N-01815-72, C3N-01815-73, C3N-01815-74, C3N-01815-75 (6 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01815-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -1 day; Method of sample procurement: Blood Draw.
